Somatic mutation profile of tumor specimen TARGET-10-PANTUZ-09A (aliquot TARGET-10-PANTUZ-09A-01D) from TARGET case TARGET-10-PANTUZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (935 days).
Specimen TARGET-10-PANTUZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34c265a1-ad01-4c08-827f-d6fe8ce6c7f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTUZ-14A (Bone Marrow Normal), aliquot TARGET-10-PANTUZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/701bebcc-c0d3-4135-ab44-7d8b3b843e04

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 5, 3'UTR 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDK5R1 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55580139; called by muse, mutect2
- HAPLN3 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs777163714, COSV100613805; called by muse, mutect2, varscan2
- IGHD2-2 | c.30_31insG | In Frame Ins (INS) | VAF 28/36 reads (78%) | catalogued as rs781939562; called by mutect2, pindel*, varscan2
- ZMIZ1 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs757776712; called by muse, mutect2, varscan2
- FNDC1 | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ZNF385D | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC12A1 | c.261C>T p.H87= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- CEP170 | c.4319+72G>A | Intron (SNP) | VAF 16/80 reads (20%) | catalogued as rs1387400134; called by mutect2, varscan2
- DST | c.4297-4588G>A | Intron (SNP) | VAF 48/170 reads (28%) | catalogued as rs370912424; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAP1L1 | c.430-515G>A | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as rs1028125084; called by muse, mutect2
- NEB | c.8890-2927G>A | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1176194037, COSV99413854; called by muse, mutect2
- OR2L2 | c.*67A>G | 3'UTR (SNP) | VAF 16/80 reads (20%) | catalogued as rs1032833694; called by muse, mutect2, varscan2
- SPTLC1 | c.166-57C>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs1262143069; called by muse, mutect2, varscan2
